Somatic mutation profile of tumor specimen TCGA-EE-A29R-06A (aliquot TCGA-EE-A29R-06A-11D-A197-08) from TCGA case TCGA-EE-A29R, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 49.4 years (18,028 days).
Specimen TCGA-EE-A29R-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d237e4a-a5ee-4875-81a2-dab091041f43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A29R-10A (Blood Derived Normal), aliquot TCGA-EE-A29R-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/152eb7ee-25d7-4c5f-8b69-2651d595a5b0

The open-access MAF lists 810 somatic variants for this specimen: 512 protein-altering or splice-affecting, 275 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 463, Silent 275, Nonsense Mutation 32, Splice Site 9, Intron 9, RNA 7, Splice Region 5, 3'Flank 3, 3'UTR 2, 5'UTR 2, Frame Shift Ins 1, Translation Start Site 1.

Variants (750 of 810; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 28/58 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1057519732, COSV61068297; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 107/124 reads (86%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AADAC | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs752890596, COSV51758243, COSV51758945; called by muse, mutect2, varscan2
- ACOT12 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs113234186, COSV56892781; called by muse, mutect2, varscan2
- ACSL5 | c.740C>T p.P247L (on ENST00000354273; = p.P303L on NM_016234.3) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV61128992; called by muse, mutect2, varscan2
- ACTR10 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as COSV54297509; called by muse, mutect2, varscan2
- ADAMDEC1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.78); PolyPhen benign (0.01); catalogued as COSV56474162; called by muse, mutect2, varscan2
- ADAMTS10 | c.3253C>T p.Q1085* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV54352331; called by muse, mutect2, varscan2
- ADAMTS18 | c.974T>A p.V325D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51399354; called by muse, mutect2, varscan2
- ADAMTS19 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.098); catalogued as COSV50733189; called by muse, mutect2, varscan2
- ADAMTS2 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755997172, COSV51072403; called by muse, mutect2, varscan2
- ADAMTS7 | c.3752C>T p.S1251F | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV66306075; called by muse, mutect2
- ADCY2 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV57860306, COSV57874595; called by muse, varscan2
- ADGRA1 | c.1658C>T p.P553L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as COSV66924845; called by muse, mutect2, varscan2
- ADGRE3 | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 52/88 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV53728527; called by muse, mutect2, varscan2
- ADGRF1 | c.422G>A p.S141N | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV64799567; called by muse, mutect2, varscan2
- ADGRF4 | c.2014G>A p.G672R | Missense Mutation (SNP) | VAF 80/284 reads (28%) | SIFT tolerated (0.92); PolyPhen benign (0.052); catalogued as COSV51949871; called by muse, mutect2, varscan2
- ADGRV1 | c.8588C>T p.T2863I | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.143); catalogued as COSV67979216; called by muse, mutect2, varscan2
- ADH1B | c.904C>T p.L302F | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as COSV59295242; called by muse, mutect2, varscan2
- AFF3 | c.3206C>T p.A1069V | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57842010; called by muse, mutect2, varscan2
- AFF3 | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as rs1210825632, COSV57842019; called by muse, mutect2, varscan2
- AGAP6 | c.1505C>T p.P502L (on ENST00000374056 / NM_001365867.1; = p.P525L on NM_001077665.2) | Missense Mutation (SNP) | VAF 94/184 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65017342; called by muse, mutect2, varscan2
- AGXT2 | c.1015C>T p.H339Y | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51484176; called by muse, mutect2, varscan2
- AIRE | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs966636123, COSV52392733; called by muse, mutect2, varscan2
- AKAP8 | c.1601A>G p.K534R | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV54101172; called by muse, mutect2
- AKAP9 | c.3589G>A p.E1197K | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); catalogued as COSV62339581; called by muse, mutect2, varscan2
- ALDH3A2 | c.527A>G p.Q176R | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.474); catalogued as COSV51565715; called by muse, mutect2, varscan2
- ALDH6A1 | c.1478G>C p.G493A | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63245853, COSV63245924; called by muse, mutect2, varscan2
- AMER3 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1200629352, COSV58465055; called by muse, mutect2, varscan2
- ANK1 | c.4165C>T p.L1389F | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as rs1204896407, COSV55873929; called by muse, mutect2, varscan2
- ANKLE2 | c.1648C>T p.L550F | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61707969; called by muse, mutect2, varscan2
- ANKRD55 | c.1448G>A p.R483K | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.023); catalogued as COSV61944514; called by muse, mutect2, varscan2
- AOAH | c.805C>T p.H269Y | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51736123; called by muse, mutect2, varscan2
- APOB | c.9635G>A p.R3212K | Missense Mutation (SNP) | VAF 172/506 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs774659447, COSV51924762, COSV51930251; called by muse, mutect2, varscan2
- APPL1 | c.1669C>T p.P557S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55699859; called by muse, mutect2, varscan2
- APPL1 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV55699870, COSV99897215; called by muse, mutect2, varscan2
- ARMC4 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as rs763298147, COSV53462861; called by muse, mutect2, varscan2
- ARRB2 | c.859G>A p.G287S | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52616585; called by muse, mutect2, varscan2
- ASAH2 | c.161G>A p.S54N | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV61484528; called by muse, mutect2
- ASXL3 | c.4157C>T p.S1386F | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.647); catalogued as COSV52458388; called by muse, mutect2, varscan2
- ATF1 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs763994606, COSV50394055; called by muse, mutect2, varscan2
- ATIC | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV52691983; called by muse, mutect2, varscan2
- ATP1A3 | c.1232G>A p.G411E (on ENST00000545399 / NM_001256214.2; = p.G398E on NM_152296.5) | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.872); catalogued as COSV57485267; called by muse, mutect2, varscan2
- ATP2B2 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 126/267 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV59490313, COSV99080519; called by muse, varscan2
- ATRN | c.2015C>T p.S672L | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs760968702, COSV53524269; called by muse, mutect2, varscan2
- ATXN2L | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV57365857, COSV57371185; called by muse, mutect2, varscan2
- AUH | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT tolerated (0.46); PolyPhen benign (0.031); catalogued as COSV57861723; called by muse, mutect2, varscan2
- BCAR3 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT tolerated (0.07); PolyPhen benign (0.365); catalogued as COSV53072446; called by muse, mutect2, varscan2
- BEX5 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV61328355; called by muse, mutect2, varscan2
- BMP10 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs771100602, COSV54894135; called by muse, mutect2, varscan2
- BNIPL | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs150851524; called by muse, mutect2, varscan2
- BPIFB1 | c.991A>G p.K331E | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs1490484096, COSV53605241; called by muse, mutect2, varscan2
- BRINP1 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 34/37 reads (92%) | SIFT tolerated (0.25); PolyPhen benign (0.151); catalogued as rs763882375, COSV56292953; called by muse, mutect2, varscan2
- BRINP3 | c.1854G>A p.W618* | Nonsense Mutation (SNP) | VAF 165/447 reads (37%) | catalogued as COSV66513576, COSV66524701; called by muse, mutect2, varscan2
- C1GALT1 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56178811; called by muse, mutect2
- C1GALT1 | c.507T>A p.D169E | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56178829; called by muse, mutect2
- C2CD2 | c.1835G>A p.S612N | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV61598886; called by muse, mutect2
- C2CD2 | c.1833G>T p.M611I | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV61598895; called by muse, mutect2
- C2CD2 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs1380087553, COSV61598901; called by muse, mutect2, varscan2
- C2CD5 | c.2719C>T p.R907W | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753259599, COSV61723055; called by muse, mutect2, varscan2
- C8orf34 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs771361055, COSV57397940; called by muse, mutect2, varscan2
- CACNA1F | c.3149G>A p.G1050E | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59903210; called by muse, mutect2, varscan2
- CACNA1G | c.3071C>T p.S1024F | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.212); catalogued as rs1568090597, COSV61720716; called by muse, mutect2, varscan2
- CASP14 | c.68T>G p.L23R | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55664849; called by muse, mutect2, varscan2
- CC2D1A | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV58781395; called by muse, mutect2, varscan2
- CCDC181 | c.1012C>T p.R338* | Nonsense Mutation (SNP) | VAF 45/121 reads (37%) | catalogued as rs751919148, COSV63155774; called by muse, mutect2, varscan2
- CCDC54 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as COSV53758065; called by muse, mutect2, varscan2
- CCDC88C | c.2178G>A p.M726I | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV66234516; called by muse, mutect2, varscan2
- CCK | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs370480453; called by muse, mutect2, varscan2
- CCNB3 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 40/44 reads (91%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV52070089, COSV52070221; called by muse, mutect2, varscan2
- CCNJL | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57443156; called by muse, mutect2, varscan2
- CCT8L2 | c.1036A>C p.K346Q | Missense Mutation (SNP) | VAF 143/159 reads (90%) | SIFT tolerated (0.29); PolyPhen benign (0.102); catalogued as COSV63461701; called by muse, mutect2, varscan2
- CD163 | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.648); catalogued as rs745697104, COSV63129837; called by muse, varscan2
- CD163 | c.280T>G p.C94G | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63129847; called by muse, varscan2
- CD27 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV56949619; called by muse, mutect2, varscan2
- CD96 | c.72A>T p.E24D | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV51913053; called by muse, mutect2, varscan2
- CDCP2 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 45/48 reads (94%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs140548583; called by muse, mutect2, varscan2
- CDH11 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs868248780, COSV51752373; called by muse, mutect2, varscan2
- CDH13 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51794675, COSV51871792; called by muse, mutect2, varscan2
- CDH6 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as COSV54064950; called by muse, mutect2
- CDH7 | c.1970G>A p.G657D | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59882083; called by muse, mutect2, varscan2
- CDX4 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV100999156; called by muse, mutect2, varscan2
- CDX4 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV100999157; called by muse, mutect2, varscan2
- CEACAM5 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.414); catalogued as COSV55750875; called by muse, mutect2, varscan2
- CELSR3 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV50840819; called by muse, mutect2, varscan2
- CEP290 | c.1900C>T p.Q634* | Nonsense Mutation (SNP) | VAF 3/8 reads (38%) | catalogued as COSV58349184; called by muse, mutect2
- CEP63 | c.170G>C p.R57P | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59674634; called by muse, mutect2, varscan2
- CERKL | c.1649G>A p.G550E (on ENST00000339098 / NM_001030311.2; = p.G524E on NM_201548.5) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs1377681766, COSV59203862; called by muse, varscan2
- CETN3 | c.362G>A p.R121K | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.067); catalogued as COSV51616858; called by muse, mutect2, varscan2
- CFAP299 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV63871516; called by muse, varscan2
- CFAP47 | c.5369C>T p.S1790L | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57971566; called by muse, mutect2, varscan2
- CFHR5 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV56818401; called by muse, mutect2, varscan2
- CHD6 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.019); catalogued as COSV58554226; called by muse, mutect2, varscan2
- CHST4 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV58296559; called by muse, mutect2, varscan2
- CMYA5 | c.6859G>A p.E2287K | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.03); catalogued as COSV71404201; called by muse, mutect2, varscan2
- CNTN4 | c.219G>A p.M73I | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT tolerated (0.41); PolyPhen benign (0.063); catalogued as COSV68563822; called by muse, mutect2, varscan2
- COL1A1 | c.104-1G>A p.X35_splice | Splice Site (SNP) | VAF 68/144 reads (47%) | catalogued as CS1414695, CS151745, CS157527, COSV56802802; called by muse, mutect2, varscan2
- COL22A1 | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.857); catalogued as rs778667471, COSV57325080; called by muse, mutect2, varscan2
- COL25A1 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs771725479, COSV67646761; called by muse, mutect2, varscan2
- COL4A2 | c.4895G>A p.G1632E | Missense Mutation (SNP) | VAF 76/115 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64625202; called by muse, mutect2, varscan2
- COL4A2 | c.5052C>A p.F1684L | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV64625206, COSV64628529; called by muse, mutect2, varscan2
- COL4A5 | c.2539G>A p.D847N | Missense Mutation (SNP) | VAF 47/53 reads (89%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs1244012104, COSV60356784; called by muse, mutect2, varscan2
- COL5A3 | c.3436C>T p.P1146S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV53406721; called by muse, mutect2, varscan2
- COL9A2 | c.1793-1G>A p.X598_splice | Splice Site (SNP) | VAF 16/17 reads (94%) | catalogued as COSV65622185; called by muse, mutect2
- CPNE5 | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 118/185 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55194891; called by muse, mutect2, varscan2
- CPSF1 | c.4249G>A p.E1417K | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV58232332; called by muse, mutect2
- CR2 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65506189; called by muse, mutect2, varscan2
- CRYBG2 | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 34/41 reads (83%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.027); catalogued as COSV57483989; called by muse, mutect2, varscan2
- CSMD1 | c.9977G>A p.G3326E (on ENST00000520002; = p.G3325E on NM_033225.6) | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59286808; called by muse, mutect2, varscan2
- CSMD3 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.856); catalogued as COSV52105591, COSV52111082; called by muse, mutect2, varscan2
- CUL4A | c.1237G>A p.V413M (on ENST00000375440 / NM_001008895.4; = p.V313M on NM_003589.3) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.649); catalogued as COSV58371445; called by muse, mutect2, varscan2
- CYFIP2 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 92/199 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV59029272; called by muse, mutect2, varscan2
- CYP11B1 | c.182A>G p.Y61C | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.814); catalogued as rs1410691484, COSV52825129; called by muse, mutect2, varscan2
- CYP27C1 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV58866290; called by muse, mutect2, varscan2
- DBNL | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs145524590, COSV68882501; called by muse, mutect2, varscan2
- DEFB118 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV53619708; called by muse, mutect2, varscan2
- DIS3 | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV66705666; called by muse, mutect2, varscan2
- DISC1 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.368); catalogued as COSV54401182; called by muse, mutect2, varscan2
- DLC1 | c.2542C>T p.H848Y (on ENST00000276297 / NM_001348081.2; = p.H411Y on NM_006094.5) | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.274); catalogued as COSV52291685; called by muse, mutect2, varscan2
- DLGAP2 | c.1295G>A p.R432K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV70094689; called by muse, mutect2, varscan2
- DLX5 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV56031794; called by muse, mutect2, varscan2
- DNAH5 | c.13519G>A p.A4507T | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV54206403; called by muse, mutect2, varscan2
- DNAH9 | c.2900C>T p.S967F | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV52335986; called by muse, mutect2, varscan2
- DNAH9 | c.10624G>A p.E3542K | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs1265739679, COSV52336009, COSV52343578; called by muse, mutect2, varscan2
- DNAJC24 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); catalogued as COSV71938535; called by muse, mutect2, varscan2
- DOK7 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.73); PolyPhen benign (0.108); catalogued as rs1399458903, COSV100403582; called by muse, mutect2, varscan2
- DPT | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63189596; called by muse, mutect2, varscan2
- DSCAM | c.4981G>A p.D1661N | Missense Mutation (SNP) | VAF 89/251 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.644); catalogued as rs748635134, COSV68021632; called by muse, mutect2, varscan2
- DSCAM | c.4750G>A p.E1584K | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as rs758792903, COSV68021636; called by muse, mutect2, varscan2
- DSCAM | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 114/195 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV68624973, COSV68627433; called by muse, mutect2, varscan2
- DSCAML1 | c.3124G>A p.E1042K (on ENST00000321322; = p.E982K on NM_020693.4) | Missense Mutation (SNP) | VAF 123/141 reads (87%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as COSV58382665; called by muse, mutect2, varscan2
- DSG3 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV57124458, COSV57125106; called by muse, mutect2, varscan2
- DTX3 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.078); catalogued as COSV54084739; called by muse, mutect2, varscan2
- DYNAP | c.445C>T p.Q149* (on ENST00000321600; = p.Q123* on NM_173629.3) | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV58666045; called by muse, mutect2, varscan2
- DYRK2 | c.1517C>T p.P506L (on ENST00000344096 / NM_006482.3; = p.P433L on NM_003583.4) | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV59845397; called by muse, mutect2, varscan2
- DYTN | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101484376; called by muse, mutect2, varscan2
- DYTN | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV71751613; called by muse, mutect2, varscan2
- EBF2 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV68776252; called by muse, mutect2, varscan2
- EFHD1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1370720165, COSV51131911; called by muse, mutect2, varscan2
- EHMT2 | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 139/864 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV64994694; called by muse, mutect2, varscan2
- ELAVL4 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 60/66 reads (91%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); catalogued as COSV63914678; called by muse, mutect2, varscan2
- ENAH | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 109/218 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52865413; called by muse, mutect2, varscan2
- EPC1 | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.211); catalogued as COSV53923428; called by muse, mutect2, varscan2
- ERBB4 | c.1645G>A p.G549S | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); catalogued as rs1225202423, COSV53505721; called by muse, mutect2, varscan2
- ERCC4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 27/87 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV61314511; called by muse, mutect2, varscan2
- ERCC4 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as rs373789508; called by muse, mutect2, varscan2
- ESPNL | c.2805G>A p.W935* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as rs1279748417, COSV58032577; called by muse, mutect2
- ETS2 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV62872332; called by muse, mutect2, varscan2
- EXOSC9 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV54664999; called by muse, mutect2, varscan2
- EXPH5 | c.5674G>A p.E1892K | Missense Mutation (SNP) | VAF 42/47 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1354930025, COSV56199241; called by muse, mutect2, varscan2
- F5 | c.3124C>T p.P1042S | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as rs1469535561, COSV63121071; called by muse, mutect2, varscan2
- FABP12 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64616649; called by muse, mutect2, varscan2
- FAM160B1 | c.2009C>T p.P670L | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV65087373; called by muse, mutect2, varscan2
- FAM71C | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV60942684, COSV60943367; called by muse, mutect2, varscan2
- FAM90A1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.14); catalogued as rs777961138, COSV56710265; called by muse, mutect2, varscan2
- FAM98B | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.709); catalogued as rs754715168, COSV59842604, COSV59843280; called by muse, mutect2, varscan2
- FAT1 | c.13124C>T p.S4375L | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs769928509, COSV71672134; called by muse, mutect2, varscan2
- FAT4 | c.10519G>A p.D3507N | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58673109, COSV58714951; called by muse, mutect2, varscan2
- FBRS | c.1166C>T p.A389V (on ENST00000287468; = p.A909V on NM_001105079.3) | Missense Mutation (SNP) | VAF 76/142 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.611); catalogued as rs1312833598; called by muse, mutect2
- FBXL13 | c.1565G>A p.G522E | Missense Mutation (SNP) | VAF 39/50 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57535183; called by muse, mutect2, varscan2
- FCGR1A | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 91/193 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64985194; called by muse, mutect2, varscan2
- FGL1 | c.780-1G>A p.X260_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as COSV101112506; called by muse, mutect2
- FLG2 | c.6875G>A p.G2292E | Missense Mutation (SNP) | VAF 135/296 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.286); catalogued as COSV66166865; called by muse, mutect2, varscan2
- FLRT2 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58136901, COSV58145305, COSV58149031; called by muse, mutect2, varscan2
- FLT3 | c.882G>A p.E294= | Splice Region (SNP) | VAF 14/138 reads (10%) | catalogued as COSV54045620; called by mutect2, varscan2
- FMN2 | c.4526G>A p.G1509E | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60418659; called by muse, mutect2, varscan2
- FMO5 | c.1342A>T p.N448Y | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54204676; called by muse, mutect2, varscan2
- FOXA2 | c.154G>A p.G52S (on ENST00000377115 / NM_153675.3; = p.G58S on NM_021784.5) | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV65795689; called by muse, mutect2, varscan2
- FOXR2 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV59257898; called by muse, mutect2, varscan2
- FRAS1 | c.3901G>A p.D1301N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs369945274; called by muse, mutect2, varscan2
- FSIP2 | c.20485G>A p.E6829K | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.214); catalogued as COSV100553846, COSV58079049; called by muse, mutect2, varscan2
- GABRB1 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54972127; called by muse, mutect2, varscan2
- GABRR3 | c.477G>A p.M159I | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV101512261, COSV72084010; called by muse, mutect2, varscan2
- GALNT17 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 56/71 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs774180231, COSV61149361, COSV61166524; called by muse, mutect2, varscan2
- GALNT6 | c.1556G>A p.G519E | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV62541700; called by muse, mutect2, varscan2
- GALNTL5 | c.1160G>A p.W387* | Nonsense Mutation (SNP) | VAF 44/60 reads (73%) | catalogued as COSV67179395; called by muse, mutect2, varscan2
- GANAB | c.1891C>T p.P631S | Missense Mutation (SNP) | VAF 49/55 reads (89%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs746137972, COSV60462317; called by muse, mutect2, varscan2
- GAS2L2 | c.1240G>A p.G414R | Missense Mutation (SNP) | VAF 87/219 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs267604815; called by muse, mutect2, varscan2
- GCM2 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV65275160; called by muse, mutect2, varscan2
- GIN1 | c.133T>G p.F45V | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV67536042; called by muse, mutect2, varscan2
- GLB1 | c.1508C>T p.S503F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV56561613; called by muse, mutect2, varscan2
- GP5 | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.047); catalogued as rs769240414, COSV55461857; called by muse, mutect2, varscan2
- GPC4 | c.1114G>T p.E372* | Nonsense Mutation (SNP) | VAF 136/162 reads (84%) | catalogued as COSV63696991, COSV63698295; called by muse, varscan2
- GPR39 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0.053); catalogued as COSV61421401; called by muse, mutect2, varscan2
- GZMK | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV50244207; called by muse, mutect2, varscan2
- H1-3 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 51/357 reads (14%) | catalogued as rs1208487692, COSV55096949; called by muse, mutect2, varscan2
- HAND2 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.288); catalogued as COSV64017790; called by muse, mutect2, varscan2
- HELQ | c.2719C>T p.L907F | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV55024257; called by muse, mutect2, varscan2
- HELZ | c.4546C>T p.Q1516* | Nonsense Mutation (SNP) | VAF 38/94 reads (40%) | catalogued as COSV62376516; called by muse, mutect2, varscan2
- HEPHL1 | c.2288G>A p.G763E | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772244521, COSV59889767; called by muse, mutect2, varscan2
- HIVEP1 | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV65099015; called by muse, mutect2, varscan2
- HLA-DRA | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 75/272 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV66622558; called by muse, mutect2, varscan2
- HOXD4 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 84/162 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.095); catalogued as COSV60459335; called by muse, mutect2, varscan2
- HPR | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs767329034, COSV57181650; called by muse, mutect2, varscan2
- HRNR | c.2605C>T p.Q869* | Nonsense Mutation (SNP) | VAF 71/133 reads (53%) | catalogued as COSV64254942; called by muse, mutect2, varscan2
- HSD11B1 | c.274A>C p.T92P | Missense Mutation (SNP) | VAF 121/300 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.38); catalogued as COSV54826083; called by muse, mutect2, varscan2
- HTR1A | c.305G>A p.W102* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as rs1175917615, COSV60499659; called by muse, mutect2, varscan2
- HTR1F | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.3); PolyPhen benign (0.345); catalogued as COSV60389051; called by muse, mutect2, varscan2
- HYDIN | c.6605C>T p.T2202I | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.097); catalogued as COSV59250365; called by muse, mutect2, varscan2
- HYDIN | c.2545C>T p.L849F | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.962); catalogued as COSV100376768, COSV58547796; called by muse, mutect2, varscan2
- IARS2 | c.2494C>T p.R832C | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56957822; called by muse, mutect2, varscan2
- IGDCC4 | c.2236C>T p.Q746* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV61535591; called by muse, mutect2, varscan2
- IGHD | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs748712500, COSV101163028; called by muse, mutect2
- IGHV3-7 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.009); catalogued as rs565443498; called by muse, mutect2
- IL18RAP | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as rs1202570474, COSV51824112; called by muse, mutect2, varscan2
- IL1R1 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52104786; called by muse, mutect2, varscan2
- IL2RG | c.59G>C p.G20A | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV52147307; called by muse, mutect2, varscan2
- INTS1 | c.3031C>T p.P1011S | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV67176485, COSV67178485; called by muse, mutect2, varscan2
- IQGAP3 | c.2875C>T p.L959F | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63249618; called by muse, mutect2, varscan2
- IQGAP3 | c.1204T>C p.C402R | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.08); catalogued as COSV63249625; called by muse, mutect2
- ITGA8 | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs138187704; called by muse, mutect2, varscan2
- ITGA8 | c.2206A>T p.T736S | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.669); catalogued as COSV65225198, COSV65227912; called by muse, mutect2, varscan2
- ITGA8 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.254); catalogued as rs144983869, COSV65232856; called by muse, mutect2, varscan2
- ITGB7 | c.2340T>G p.S780R | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs763992669, COSV99914264; called by muse, mutect2, varscan2
- ITGB7 | c.2339G>A p.S780N | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs200024920, COSV99914266; called by muse, mutect2, varscan2
- JPT1 | c.155T>C p.F52S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as COSV59172807; called by muse, mutect2, varscan2
- KBTBD6 | c.1382G>A p.R461K | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.07); catalogued as COSV65270942, COSV65271151; called by muse, mutect2, varscan2
- KCNH6 | c.2414G>A p.R805K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); catalogued as rs1568089232, COSV59001065; called by muse, mutect2, varscan2
- KCNH7 | c.484T>A p.F162I | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV59786666; called by muse, mutect2, varscan2
- KCNK1 | c.300G>A p.W100* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | catalogued as COSV64037185; called by muse, mutect2, varscan2
- KCNT2 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1452776560, COSV54065701; called by muse, mutect2, varscan2
- KIAA1109 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV52663369; called by muse, mutect2, varscan2
- KIAA1109 | c.13870C>T p.R4624* | Nonsense Mutation (SNP) | VAF 57/113 reads (50%) | catalogued as rs1173401853, COSV52663384; called by muse, mutect2, varscan2
- KIAA1217 | c.2770A>G p.T924A | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV56812816; called by muse, mutect2, varscan2
- KIF27 | c.1762C>T p.H588Y | Missense Mutation (SNP) | VAF 55/68 reads (81%) | SIFT tolerated (1); PolyPhen benign (0.123); catalogued as COSV52825472; called by muse, mutect2, varscan2
- KIT | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as COSV55390118; called by muse, mutect2, varscan2
- KLHL15 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 59/72 reads (82%) | SIFT tolerated (0.71); PolyPhen benign (0.154); catalogued as COSV60139301; called by muse, mutect2, varscan2
- KLHL4 | c.1084G>A p.G362R | Missense Mutation (SNP) | VAF 54/74 reads (73%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV64139420; called by muse, mutect2, varscan2
- KRTAP10-7 | c.56T>C p.V19A | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.938); catalogued as COSV59109527; called by muse, mutect2, varscan2
- KRTAP13-3 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV61878619; called by muse, mutect2, varscan2
- LAMA2 | c.5062G>A p.D1688N | Missense Mutation (SNP) | VAF 35/39 reads (90%) | SIFT tolerated (0.7); PolyPhen benign (0.057); catalogued as COSV70339679; called by muse, mutect2, varscan2
- LAYN | c.463C>T p.H155Y (on ENST00000375615 / NM_001258390.1; = p.H147Y on NM_178834.5) | Missense Mutation (SNP) | VAF 38/46 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs763383905, COSV65104453; called by muse, mutect2, varscan2
- LDB2 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV58763279; called by muse, mutect2, varscan2
- LMBRD1 | c.984C>T p.I328= (on ENST00000649011; = p.I306= on NM_018368.4) | Splice Region (SNP) | VAF 15/19 reads (79%) | catalogued as rs766287809, COSV65296243; ClinVar: likely benign; called by muse, mutect2, varscan2
- LPA | c.5413G>A p.D1805N | Missense Mutation (SNP) | VAF 57/63 reads (90%) | SIFT tolerated (0.13); PolyPhen benign (0.322); catalogued as COSV60297614; called by muse, mutect2, varscan2
- LRP1B | c.3311G>A p.W1104* | Nonsense Mutation (SNP) | VAF 51/95 reads (54%) | catalogued as COSV101250863, COSV67190351; called by muse, mutect2, varscan2
- LRRC37A3 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.775); catalogued as COSV100141499; called by mutect2, varscan2
- LTBP1 | c.2841G>A p.M947I (on ENST00000404816 / NM_206943.4; = p.M621I on NM_000627.4) | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV63179097; called by muse, mutect2, varscan2
- LYPD3 | c.213C>T p.I71= | Splice Region (SNP) | VAF 26/40 reads (65%) | catalogued as COSV54987899; called by muse, mutect2, varscan2
- MAF | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58153223; called by muse, mutect2, varscan2
- MAP1B | c.5254G>A p.D1752N | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT tolerated (0.8); PolyPhen benign (0.158); catalogued as rs569299339, COSV57094368; called by muse, mutect2, varscan2
- MAP3K15 | c.3847C>T p.L1283F | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs1448313019, COSV58826377; called by muse, mutect2, varscan2
- MAPK8 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV100827541, COSV64409311; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3335G>A p.R1112K | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1338011041, COSV51599185; called by muse, mutect2, varscan2
- MATN2 | c.2204G>A p.G735E | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54707184; called by muse, mutect2
- MBD5 | c.2731C>T p.P911S | Missense Mutation (SNP) | VAF 134/243 reads (55%) | SIFT tolerated (0.47); PolyPhen benign (0.26); catalogued as rs753274698, COSV68695860; called by muse, mutect2, varscan2
- MBTD1 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV64502850; called by muse, mutect2, varscan2
- MCM2 | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54032174; called by muse, mutect2, varscan2
- MCTP2 | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs923946041, COSV59140793, COSV59141197; called by muse, mutect2, varscan2
- MCTP2 | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV63291858; called by muse, mutect2, varscan2
- MDH1B | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs779726212, COSV65588630; called by muse, mutect2, varscan2
- MEF2C | c.1370G>A p.R457K | Missense Mutation (SNP) | VAF 91/224 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.075); catalogued as rs1163142825, COSV100426317, COSV60926099; called by muse, mutect2, varscan2
- METTL21C | c.442A>C p.N148H | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57432164; called by muse, mutect2, varscan2
- METTL7B | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV57692247; called by muse, mutect2, varscan2
- MGA | c.4265C>T p.S1422F | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs1242451475, COSV54949496; called by muse, mutect2, varscan2
- MIA2 | c.926G>A p.W309* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as COSV54482167; called by muse, mutect2, varscan2
- MICAL2 | c.4568G>A p.R1523Q | Missense Mutation (SNP) | VAF 25/26 reads (96%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.003); catalogued as rs200474609; called by muse, mutect2, varscan2
- MIGA2 | c.1478C>T p.S493F | Missense Mutation (SNP) | VAF 89/101 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV52975936; called by muse, mutect2, varscan2
- MKRN3 | c.694A>T p.R232W | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV58808739; called by muse, mutect2, varscan2
- MPP4 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59629154; called by muse, mutect2, varscan2
- MROH2B | c.4330C>T p.P1444S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs867161694, COSV68181440; called by muse, mutect2, varscan2
- MUC16 | c.34393A>G p.I11465V | Missense Mutation (SNP) | VAF 93/153 reads (61%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV67447618; called by muse, mutect2, varscan2
- MUC16 | c.26618C>T p.S8873F | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.353); catalogued as COSV67447627; called by muse, mutect2
- MUC16 | c.20171C>T p.S6724F | Missense Mutation (SNP) | VAF 98/322 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.036); catalogued as COSV67447634; called by muse, mutect2, varscan2
- MXRA5 | c.6700C>T p.L2234F | Missense Mutation (SNP) | VAF 33/38 reads (87%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV54225179; called by muse, mutect2, varscan2
- MYBPC1 | c.2594G>A p.G865E (on ENST00000550270 / NM_206820.2; = p.G872E on NM_002465.4) | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62251243; called by muse, mutect2, varscan2
- MYH8 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as COSV67960428; called by muse, mutect2
- MYL4 | c.488-1G>A p.X163_splice | Splice Site (SNP) | VAF 22/62 reads (35%) | catalogued as rs770372675, COSV61698028; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO16 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1200275190, COSV51779265; called by muse, mutect2, varscan2
- MYO18B | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 23/25 reads (92%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV59126514; called by muse, mutect2, varscan2
- MYO18B | c.6872G>A p.R2291K | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV59126524; called by muse, mutect2, varscan2
- MYPN | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV62731822; called by muse, mutect2, varscan2
- MYT1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.037); catalogued as COSV60501529; called by muse, mutect2, varscan2
- NAA30 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV53648103; called by muse, mutect2, varscan2
- NANOG | c.444G>A p.M148I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV57550889, COSV57552063; called by muse, mutect2, varscan2
- NBEA | c.6049G>A p.E2017K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59762759; called by muse, mutect2, varscan2
- NCF2 | c.1290+1G>A p.X430_splice | Splice Site (SNP) | VAF 49/100 reads (49%) | catalogued as COSV62314831; called by muse, mutect2, varscan2
- NFATC1 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.851); catalogued as rs771065897, COSV53695754; called by muse, mutect2
- NFE2L2 | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747179142, COSV67960262; called by muse, mutect2, varscan2
- NID1 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV51615375; called by muse, mutect2, varscan2
- NLRP1 | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.129); catalogued as COSV52559265; called by muse, mutect2, varscan2
- NLRP3 | c.2494T>C p.L832= | Splice Region (SNP) | VAF 39/112 reads (35%) | catalogued as rs1221750300, COSV60220624; called by muse, mutect2, varscan2
- NOL6 | c.2450C>T p.S817L | Missense Mutation (SNP) | VAF 30/33 reads (91%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as rs147925131; called by muse, mutect2, varscan2
- NOMO1 | c.2333C>T p.S778L | Missense Mutation (SNP) | VAF 58/314 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV99814866; called by muse, varscan2
- NOTCH4 | c.5897C>T p.P1966L | Missense Mutation (SNP) | VAF 353/1200 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.074); catalogued as COSV66678955; called by muse, mutect2, varscan2
- NOX1 | c.994A>T p.I332F | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV54193502; called by muse, mutect2, varscan2
- NPR1 | c.3103C>T p.R1035* | Nonsense Mutation (SNP) | VAF 41/117 reads (35%) | catalogued as COSV64117244; called by muse, mutect2, varscan2
- NPY2R | c.331A>T p.T111S | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61527332; called by muse, mutect2, varscan2
- NRG3 | c.1207A>T p.K403* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as COSV64546475; called by muse, mutect2, varscan2
- NT5C1B | c.1440T>A p.F480L (on ENST00000359846 / NM_001199086.2; = p.F420L on NM_033253.4) | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV58394534; called by muse, mutect2, varscan2
- NUTM1 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59215889; called by muse, mutect2, varscan2
- NWD1 | c.1423G>A p.V475I | Missense Mutation (SNP) | VAF 57/114 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as rs1331972755, COSV60338149; called by muse, mutect2, varscan2
- OCM | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.567); catalogued as rs755114818, COSV54194154; called by muse, varscan2
- OLA1 | c.610C>T p.H204Y | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV52967717; called by muse, mutect2, varscan2
- OLAH | c.308G>A p.G103E (on ENST00000378228 / NM_001039702.3; = p.G156E on NM_018324.3) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65491577, COSV65494707; called by muse, mutect2
- OR1D5 | c.869G>A p.R290K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV101643444; called by mutect2, varscan2
- OR2M2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 90/378 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as COSV62897836, COSV62897885; called by muse, mutect2, varscan2
- OR4E2 | c.41T>C p.F14S | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV57731438, COSV57731715; called by muse, mutect2
- OR4X1 | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV60722295; called by muse, mutect2, varscan2
- OR5AC2 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV62279191; called by muse, mutect2, varscan2
- OR5H2 | c.113T>G p.V38G | Missense Mutation (SNP) | VAF 149/278 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as COSV62350046; called by muse, mutect2, varscan2
- OR6K3 | c.964C>T p.L322F (on ENST00000368146; = p.L306F on NM_001005327.2) | Missense Mutation (SNP) | VAF 74/187 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV100933915, COSV63745312; called by muse, mutect2, varscan2
- OR9I1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 43/51 reads (84%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as rs1487173238, COSV56925402; called by muse, mutect2, varscan2
- PAPPA2 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 118/312 reads (38%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV62773677; called by muse, mutect2, varscan2
- PCDH15 | c.4580C>T p.P1527L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.18); catalogued as COSV57267565, COSV57390652; called by muse, mutect2, varscan2
- PCDH19 | c.2643C>A p.N881K (on ENST00000373034 / NM_001184880.2; = p.N834K on NM_020766.3) | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV55258226; called by muse, mutect2, varscan2
- PCDHB7 | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs782790674, COSV50754848; called by muse, mutect2, varscan2
- PCLO | c.7775C>T p.P2592L | Missense Mutation (SNP) | VAF 128/173 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61617749, COSV61636228; called by muse, mutect2, varscan2
- PCLO | c.1690G>A p.G564R | Missense Mutation (SNP) | VAF 52/404 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as COSV61617757; called by muse, mutect2, varscan2
- PDE3B | c.931T>C p.C311R | Missense Mutation (SNP) | VAF 78/86 reads (91%) | SIFT tolerated (0.05); PolyPhen benign (0.143); catalogued as COSV56380088; called by muse, mutect2, varscan2
- PDE4A | c.1225C>T p.R409C (on ENST00000380702 / NM_001111307.2; = p.R170C on NM_006202.3) | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs201196140, COSV53351248; called by muse, mutect2, varscan2
- PDHB | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 27/52 reads (52%) | catalogued as COSV57056411; called by muse, mutect2, varscan2
- PDLIM1 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV61473530; called by muse, mutect2, varscan2
- PEG3 | c.2455C>T p.R819C | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs143073381; called by muse, mutect2, varscan2
- PELI2 | c.310-2A>G p.X104_splice | Splice Site (SNP) | VAF 8/18 reads (44%) | catalogued as COSV50710064; called by muse, varscan2
- PELI2 | c.364G>C p.G122R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50710067, COSV50710682; called by muse, varscan2
- PHF21B | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 53/55 reads (96%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV57556195; called by muse, mutect2, varscan2
- PHF21B | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 76/80 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57556199; called by muse, mutect2, varscan2
- PICK1 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 60/66 reads (91%) | catalogued as COSV104418826, COSV63659564; called by muse, mutect2, varscan2
- PIGT | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54125180; called by muse, mutect2, varscan2
- PKD1L1 | c.6104G>A p.G2035E | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV56958724; called by muse, mutect2, varscan2
- PKHD1L1 | c.10108G>A p.G3370R | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV65738101; called by muse, varscan2
- PLCH1 | c.4813C>T p.P1605S (on ENST00000340059 / NM_001130960.2; = p.P1597S on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/144 reads (53%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as COSV58188309; called by muse, mutect2, varscan2
- PLCL1 | c.3022A>G p.N1008D | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV70821734; called by muse, mutect2, varscan2
- PLCL2 | c.457C>T p.R153C (on ENST00000615277 / NM_001144382.2; = p.R27C on NM_015184.5) | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1462336512, COSV67620691; called by muse, mutect2
- PLXDC2 | c.1541T>C p.V514A | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65901122; called by muse, mutect2, varscan2
- POU6F2 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as COSV68868160; called by muse, mutect2
- PPIC | c.611C>A p.P204H | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1459263781, COSV60574330, COSV60574695; called by muse, mutect2, varscan2
- PPP1R13B | c.2023C>T p.L675F | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52449002; called by muse, mutect2, varscan2
- PPP4R4 | c.2612C>T p.S871F | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1392343941, COSV56227540; called by muse, varscan2
- PPP5C | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50139279, COSV50139287; called by muse, mutect2, varscan2
- PPP6C | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101001267, COSV65207059; called by muse, mutect2, varscan2
- PRCD | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.277); catalogued as COSV99506258; called by muse, mutect2, varscan2
- PRDM16 | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 87/96 reads (91%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as COSV54580047; called by muse, mutect2, varscan2
- PRG4 | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 171/353 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV63355025; called by muse, mutect2, varscan2
- PSD | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50042029; called by muse, mutect2
- PSG3 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 66/203 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs151272583; called by muse, mutect2, varscan2
- PSMD2 | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV59529029; called by muse, mutect2, varscan2
- PTCHD1 | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 61/70 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65059166; called by muse, mutect2, varscan2
- PTGER2 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV55418212; called by muse, mutect2, varscan2
- PTPRB | c.1499C>T p.S500F | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.958); catalogued as rs373810196; called by muse, mutect2, varscan2
- PTPRD | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 82/93 reads (88%) | SIFT tolerated (0.37); PolyPhen benign (0.054); catalogued as rs757922864, COSV61929535; called by muse, mutect2, varscan2
- PTPRD | c.1401G>A p.M467I | Missense Mutation (SNP) | VAF 114/122 reads (93%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV61930344, COSV61947533; called by muse, mutect2, varscan2
- PTPRN2 | c.922C>T p.H308Y | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV67024317; called by muse, mutect2, varscan2
- PTPRT | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs868376470, COSV61962472; called by muse, mutect2, varscan2
- PTTG1IP | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 51/88 reads (58%) | SIFT tolerated (0.41); PolyPhen benign (0.187); catalogued as rs372394942; called by muse, mutect2, varscan2
- PWWP3B | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as COSV61798439; called by muse, mutect2, varscan2
- PXDNL | c.1616A>T p.Q539L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV62479574; called by muse, mutect2, varscan2
- RAB40AL | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 34/59 reads (58%) | catalogued as rs781310794, COSV99505277; called by muse, mutect2, varscan2
- RABGAP1L | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs751561117, COSV52278381; called by muse, mutect2, varscan2
- RAD51AP2 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as COSV67587378; called by muse, mutect2, varscan2
- RANBP6 | c.2149C>T p.P717S | Missense Mutation (SNP) | VAF 73/81 reads (90%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV52388332; called by muse, mutect2, varscan2
- RASGRP1 | c.327C>T p.L109= | Splice Region (SNP) | VAF 30/76 reads (39%) | catalogued as COSV60363801; called by muse, mutect2, varscan2
- RET | c.2221G>A p.A741T | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60687656; called by muse, mutect2, varscan2
- RHOBTB1 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 105/253 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758661809, COSV61957833; called by muse, mutect2, varscan2
- ROBO1 | c.4523T>A p.V1508E | Missense Mutation (SNP) | VAF 94/177 reads (53%) | SIFT tolerated (0.96); PolyPhen benign (0.01); catalogued as COSV71392040; called by muse, mutect2
- RPGRIP1 | c.2986G>A p.E996K | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV52843842; called by muse, mutect2, varscan2
- RRP12 | c.3316C>T p.R1106W | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as rs1022564921, COSV59665113; called by muse, mutect2, varscan2
- RSPH1 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 78/239 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763212999, COSV52318475; called by muse, mutect2, varscan2
- RYR2 | c.4192A>C p.S1398R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.382); catalogued as COSV63664951; called by muse, varscan2
- RYR2 | c.6505G>A p.E2169K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63664965, COSV63720100; called by muse, mutect2, varscan2
- RYR3 | c.10636G>A p.E3546K (on ENST00000389232; = p.E3547K on NM_001036.6) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.888); catalogued as COSV66779237; called by muse, mutect2, varscan2
- SALL1 | c.3010G>A p.D1004N | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.722); catalogued as COSV51753827; called by muse, mutect2, varscan2
- SALL1 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV51753505, COSV51765954; called by muse, mutect2, varscan2
- SAMD4B | c.1565C>T p.S522F | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58750273; called by muse, mutect2, varscan2
- SCARF2 | c.1607C>T p.P536L | Missense Mutation (SNP) | VAF 81/85 reads (95%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV56731203; called by muse, mutect2, varscan2
- SCN1A | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs781746113, COSV57661440; called by muse, mutect2, varscan2
- SEC14L5 | c.1594G>A p.G532R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV52036656; called by muse, mutect2
- SEC16B | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV57623649; called by muse, mutect2, varscan2
- SEC31B | c.1978C>T p.P660S | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV64843747; called by muse, mutect2, varscan2
- SELP | c.1876C>T p.P626S | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.662); catalogued as COSV55248705, COSV55250219; called by muse, mutect2, varscan2
- SEMA4A | c.1325C>T p.S442L | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0.009); catalogued as rs111977724, COSV61772129; called by muse, mutect2, varscan2
- SEMA5A | c.2941C>T p.L981F | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.866); catalogued as COSV66785470; called by muse, mutect2, varscan2
- SEMA5B | c.2935G>A p.D979N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.143); catalogued as COSV52091560; called by muse, mutect2, varscan2
- SERPINB10 | c.235-1G>A p.X79_splice | Splice Site (SNP) | VAF 15/34 reads (44%) | catalogued as COSV53071648; called by muse, mutect2, varscan2
- SERPINI2 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV52984441; called by muse, mutect2, varscan2
- SGCZ | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601802, COSV65998392, COSV66047381; called by muse, mutect2, varscan2
- SGCZ | c.193G>C p.A65P | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as rs747199416, COSV65998399; called by muse, mutect2, varscan2
- SH3RF3 | c.793T>C p.Y265H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1359881689, COSV58680852; called by muse, mutect2, varscan2
- SI | c.3361G>A p.A1121T | Missense Mutation (SNP) | VAF 47/84 reads (56%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs748355409, COSV52267393, COSV52269060; called by muse, mutect2, varscan2
- SI | c.377T>C p.V126A | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1272011582, COSV52267414; called by muse, mutect2, varscan2
- SIGLEC10 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV59479323; called by muse, mutect2, varscan2
- SIN3B | c.363G>T p.Q121H | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.076); catalogued as COSV56131402; called by muse, mutect2, varscan2
- SLAMF7 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs981720195, COSV63562772; called by muse, mutect2, varscan2
- SLC10A6 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV56720754; called by muse, mutect2, varscan2
- SLC13A2 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV58992799; called by muse, mutect2, varscan2
- SLC13A2 | c.1241A>G p.N414S | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV58992818; called by muse, mutect2, varscan2
- SLC13A5 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0.012); catalogued as COSV53421802; called by muse, mutect2, varscan2
- SLC14A2 | c.2743C>T p.Q915* | Nonsense Mutation (SNP) | VAF 40/93 reads (43%) | catalogued as COSV54906643; called by muse, mutect2, varscan2
- SLC17A2 | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as COSV55350541, COSV99614985; called by muse, mutect2, varscan2
- SLC2A9 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1560305437, COSV53317116; called by muse, mutect2, varscan2
- SLC38A11 | c.929G>A p.G310D (on ENST00000409149 / NM_001351539.1; = p.G288D on NM_173512.2) | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58052207; called by muse, mutect2, varscan2
- SLC38A5 | c.632C>T p.S211L | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.745); catalogued as rs1467306694, COSV58333463; called by muse, mutect2, varscan2
- SLC40A1 | c.633G>A p.W211* | Nonsense Mutation (SNP) | VAF 48/80 reads (60%) | catalogued as COSV53721986; called by muse, mutect2, varscan2
- SLC41A3 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59987073; called by muse, mutect2, varscan2
- SLC5A11 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 114/317 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV61740252, COSV61743283; called by muse, mutect2, varscan2
- SLC7A13 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs866902403, COSV52532727; called by muse, mutect2, varscan2
- SLC9C1 | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.914); catalogued as COSV59885407, COSV59890511; called by muse, mutect2, varscan2
- SLFN13 | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99540374; called by muse, mutect2, varscan2
- SLITRK4 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 73/89 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV62022349; called by muse, mutect2, varscan2
- SLPI | c.169T>G p.C57G | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58092021; called by muse, mutect2, varscan2
- SMCHD1 | c.3550C>T p.Q1184* | Nonsense Mutation (SNP) | VAF 33/70 reads (47%) | catalogued as COSV99862565; called by muse, mutect2
- SMG7 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV61629920; called by muse, mutect2, varscan2
- SNED1 | c.4075G>A p.E1359K | Missense Mutation (SNP) | VAF 75/257 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs572761965, COSV54087860, COSV54090683; called by muse, mutect2, varscan2
- SNRK | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as rs889935483, COSV56066227; called by muse, mutect2
- SPATA31E1 | c.3116G>A p.G1039E | Missense Mutation (SNP) | VAF 99/112 reads (88%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs1345508643, COSV57789673; called by muse, mutect2, varscan2
- SPATC1 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as COSV66298121; called by muse, mutect2, varscan2
- SPATS1 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 94/328 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1254532476, COSV55821974; called by muse, mutect2, varscan2
- SPO11 | c.1098G>A p.M366I | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV61995186; called by muse, mutect2, varscan2
- SPTB | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV67630004; called by muse, mutect2, varscan2
- SPTBN4 | c.6244G>A p.E2082K | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV58944190; called by muse, mutect2
- SPTBN5 | c.2809G>A p.E937K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.101); catalogued as rs746404663, COSV58016972; called by muse, mutect2, varscan2
- SRRM1 | c.2302C>T p.P768S | Missense Mutation (SNP) | VAF 82/91 reads (90%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV60475407; called by muse, mutect2, varscan2
- SSTR2 | c.557A>G p.N186S | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.042); catalogued as COSV59534919; called by muse, mutect2, varscan2
- ST18 | c.1864C>T p.R622* | Nonsense Mutation (SNP) | VAF 30/95 reads (32%) | catalogued as rs267601943, COSV52485545, COSV52501022, COSV52509349; called by muse, mutect2, varscan2
- ST8SIA4 | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 11/30 reads (37%) | PolyPhen probably damaging (0.974); catalogued as COSV51506594; called by muse, mutect2, varscan2
- STK33 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 113/123 reads (92%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as COSV59397040; called by muse, mutect2, varscan2
- STK38 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 74/201 reads (37%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.517); catalogued as COSV57707641; called by muse, mutect2, varscan2
- STXBP5L | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs865873766, COSV56501319; called by muse, mutect2, varscan2
- SUCO | c.3385C>T p.P1129S | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.554); catalogued as COSV99743769; called by muse, mutect2, varscan2
- SUCO | c.3386C>T p.P1129L | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); catalogued as COSV99743772; called by muse, mutect2, varscan2
- SVOP | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54464263; called by muse, mutect2, varscan2
- SYNGAP1 | c.2221C>T p.P741S | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.136); catalogued as rs760257950, COSV99538986; called by muse, mutect2
- SYNGAP1 | c.2222C>T p.P741L | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV99538989; called by muse, mutect2
- TAAR9 | c.1034T>G p.V345G | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV71512181; called by muse, varscan2
- TAF1L | c.4376C>T p.P1459L | Missense Mutation (SNP) | VAF 133/147 reads (90%) | SIFT tolerated (0.3); PolyPhen benign (0.067); catalogued as COSV54258511; called by muse, varscan2
- TBC1D32 | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 37/40 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51537248; called by muse, mutect2, varscan2
- TECPR2 | c.998C>T p.S333L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1374799971, COSV63969187; called by muse, mutect2, varscan2
- TEKT3 | c.925C>A p.L309I | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV58626055, COSV58628228; called by muse, mutect2, varscan2
- TENM3 | c.7960G>A p.E2654K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1307412985, COSV69314118; called by muse, mutect2
- TFEC | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 63/91 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs766745080, COSV55397883; called by muse, mutect2, varscan2
- TLL1 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as COSV50262779; called by muse, mutect2, varscan2
- TLL1 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV50262811, COSV50336137; called by muse, mutect2, varscan2
- TLR9 | c.1850G>A p.G617E | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as COSV62345656; called by muse, mutect2, varscan2
- TMCO4 | c.1550C>T p.A517V | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs748078179, COSV53869397; called by muse, mutect2, varscan2
- TMEM128 | c.151C>T p.H51Y (on ENST00000382753 / NM_001297552.2; = p.H27Y on NM_032927.3) | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54635984; called by muse, mutect2, varscan2
- TMEM132B | c.1852G>A p.D618N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs778222027, COSV54745792; called by muse, mutect2, varscan2
- TMEM251 | c.326T>A p.V109E (on ENST00000415050 / NM_001098621.4; = p.V77E on NM_015676.3) | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as rs756254807, COSV52092241; called by muse, mutect2, varscan2
- TMEM270 | c.229C>T p.L77F | Missense Mutation (SNP) | VAF 56/85 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs375181504; called by muse, mutect2, varscan2
- TMTC1 | c.821G>A p.G274E (on ENST00000539277 / NM_001193451.2; = p.G166E on NM_175861.3) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.188); catalogued as COSV99760949; called by muse, mutect2, varscan2
- TMTC1 | c.820G>A p.G274R (on ENST00000539277 / NM_001193451.2; = p.G166R on NM_175861.3) | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99760953; called by muse, mutect2, varscan2
- TNN | c.3802C>T p.P1268S | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV53422148, COSV99512875; called by muse, mutect2, varscan2
- TP63 | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM0910987, CS095574, COSV53197664; called by muse, mutect2, varscan2
- TRANK1 | c.4186C>T p.Q1396* | Nonsense Mutation (SNP) | VAF 69/227 reads (30%) | catalogued as COSV57141998; called by muse, mutect2, varscan2
- TRAPPC9 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs765644558, COSV66893336; called by muse, mutect2
- TRIM16 | c.1334C>T p.T445I | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV100372079; called by muse, mutect2, varscan2
- TRIM49 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs9667365; called by muse, varscan2
- TRIML1 | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 57/101 reads (56%) | SIFT tolerated (0.83); PolyPhen benign (0.062); catalogued as rs928884225, COSV60193451; called by muse, mutect2, varscan2
- TRIP4 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV56029795; called by muse, mutect2, varscan2
- TRMT44 | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.07); catalogued as COSV67663430; called by muse, mutect2, varscan2
- TRPC6 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 64/74 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749181706, COSV60251253; called by muse, mutect2, varscan2
- TSC2 | c.2303C>T p.P768L | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555506977, COSV54756880; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSC2 | c.3978G>A p.M1326I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV51911356; called by mutect2, varscan2
- TTN | c.39166G>A p.E13056K (on ENST00000591111; = p.E5632K on NM_003319.4) | Missense Mutation (SNP) | VAF 41/122 reads (34%) | PolyPhen probably damaging (0.994); catalogued as rs1356852922, COSV59905230; called by muse, mutect2, varscan2
- TTN | c.19438G>A p.D6480N (on ENST00000591111; = p.D5553N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | PolyPhen benign (0.059); catalogued as COSV59905253; called by muse, mutect2, varscan2
- TTN | c.17291C>T p.T5764I (on ENST00000591111; = p.T4837I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/47 reads (55%) | PolyPhen benign (0.003); catalogued as COSV59905262; called by muse, mutect2, varscan2
- TTN | c.16936G>A p.E5646K (on ENST00000591111; = p.E4719K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/116 reads (47%) | PolyPhen benign (0.033); catalogued as COSV59905272; called by muse, mutect2, varscan2
- TUBAL3 | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as COSV66813957; called by muse, mutect2, varscan2
- TYK2 | c.1565C>T p.S522F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV53385036; called by muse, mutect2, varscan2
- U2SURP | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.147); catalogued as COSV67530147; called by muse, mutect2, varscan2
- UBE4B | c.2906C>T p.S969F (on ENST00000343090 / NM_001105562.3; = p.S840F on NM_006048.5) | Missense Mutation (SNP) | VAF 44/47 reads (94%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV53527238; called by muse, mutect2, varscan2
- UBXN8 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.422); catalogued as COSV55664330; called by muse, mutect2, varscan2
- UGT2B15 | c.972G>A p.M324I | Missense Mutation (SNP) | VAF 78/242 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1183404881, COSV100592453; called by muse, varscan2
- UGT2B7 | c.688A>G p.K230E | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.251); catalogued as COSV59442230; called by muse, mutect2, varscan2
- UHRF1BP1L | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1411182174, COSV54434855; called by muse, mutect2, varscan2
- UNC13C | c.2782G>A p.D928N | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs778436578, COSV52846445; called by muse, mutect2, varscan2
- UNC13C | c.5189C>T p.S1730F | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.577); catalogued as COSV104391351, COSV52846461; called by muse, mutect2, varscan2
- UPF1 | c.2102T>G p.V701G (on ENST00000599848 / NM_001297549.2; = p.V690G on NM_002911.4) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.304); catalogued as COSV53193990; called by muse, mutect2, varscan2
- UPF1 | c.2890+1G>A p.X964_splice (on ENST00000599848 / NM_001297549.2; = p.X953_splice on NM_002911.4) | Splice Site (SNP) | VAF 34/97 reads (35%) | catalogued as COSV53194009; called by muse, mutect2, varscan2
- URB2 | c.1759C>T p.L587F | Missense Mutation (SNP) | VAF 150/286 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV50981717, COSV99271383; called by muse, mutect2, varscan2
- USP38 | c.2839A>T p.K947* | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as COSV61024916; called by muse, mutect2, varscan2
- UTP14C | c.2137C>T p.Q713* | Nonsense Mutation (SNP) | VAF 63/256 reads (25%) | catalogued as COSV101584390; called by muse, mutect2, varscan2
- VAT1L | c.722+1G>A p.X241_splice | Splice Site (SNP) | VAF 37/67 reads (55%) | catalogued as rs371430712; called by muse, mutect2, varscan2
- VN1R4 | c.897G>A p.W299* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV60804683; called by muse, mutect2, varscan2
- VPS13B | c.8120G>A p.R2707Q | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.738); catalogued as rs941818698, COSV62134272; called by muse, mutect2, varscan2
- VWA2 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV53905101; called by muse, mutect2, varscan2
- VWA3A | c.3506C>T p.S1169F | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1434955003, COSV55388337; called by muse, mutect2, varscan2
- VWA7 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 157/550 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs768320112, COSV63304245; called by muse, mutect2, varscan2
- VXN | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV59685314; called by muse, mutect2, varscan2
- WASHC5 | c.1340C>T p.S447L | Missense Mutation (SNP) | VAF 54/87 reads (62%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.473); catalogued as rs886062654, COSV59194337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR62 | c.1370A>G p.N457S | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1037780257, COSV54331979; called by muse, mutect2, varscan2
- WNK3 | c.3113A>T p.D1038V | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV63612119, COSV63612287; called by muse, mutect2, varscan2
- WSCD2 | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV54578498; called by muse, mutect2, varscan2
- XIRP2 | c.2956G>A p.D986N (on ENST00000628543; = p.D1161N on NM_152381.6) | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54684673; called by muse, mutect2, varscan2
- XIRP2 | c.9637G>A p.D3213N (on ENST00000628543; = p.D3388N on NM_152381.6) | Missense Mutation (SNP) | VAF 74/141 reads (52%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV54684683; called by muse, mutect2, varscan2
- XKR3 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 104/112 reads (93%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs754227654, COSV58884868; called by muse, mutect2, varscan2
- ZBTB34 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 112/122 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59859421; called by muse, mutect2, varscan2
- ZDHHC3 | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 78/132 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV56100702; called by muse, mutect2, varscan2
- ZFHX4 | c.1230dup p.L411Afs*3 | Frame Shift Ins (INS) | VAF 10/35 reads (29%) | catalogued as rs761578656; called by mutect2, varscan2
- ZFHX4 | c.4247C>T p.S1416F | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs1356004294, COSV50522407; called by muse, mutect2, varscan2
- ZFP57 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as COSV65305688; called by muse, mutect2, varscan2
- ZNF114 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as COSV59943684; called by muse, mutect2, varscan2
- ZNF224 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61241589; called by muse, mutect2, varscan2
- ZNF277 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV62463315; called by muse, mutect2, varscan2
- ZNF287 | c.1399C>T p.L467F | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV67688157; called by muse, mutect2, varscan2
- ZNF366 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV59213969; called by muse, mutect2, varscan2
- ZNF391 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs751388118, COSV55121632; called by muse, mutect2, varscan2
- ZNF440 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as COSV58370400; called by muse, mutect2, varscan2
- ZNF480 | c.677C>T p.T226I | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.067); catalogued as COSV57994762; called by muse, mutect2, varscan2
- ZNF532 | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1193203119, COSV60171990; called by muse, mutect2
- ZNF536 | c.1599G>A p.M533I | Missense Mutation (SNP) | VAF 81/138 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV62819251, COSV62832800; called by muse, mutect2, varscan2
- ZNF599 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 73/117 reads (62%) | catalogued as COSV61395564; called by muse, mutect2, varscan2
- ZNF613 | c.1488A>T p.K496N (on ENST00000293471 / NM_001031721.4; = p.K460N on NM_024840.4) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as COSV53270925; called by muse, mutect2, varscan2
- ZNF74 | c.1664C>G p.S555W | Missense Mutation (SNP) | VAF 87/98 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV62620187; called by muse, mutect2, varscan2
- ZNF99 | c.1591C>T p.H531Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV68054753; called by muse, mutect2, varscan2
- ZSCAN31 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 48/262 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as COSV60180256; called by muse, mutect2, varscan2
- ELOA3B | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.809); called by mutect2, varscan2
- FRG2C | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 84/265 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GAS2L2 | c.1241G>A p.G414E | Missense Mutation (SNP) | VAF 86/218 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- PHEX | c.2185_2199del p.K729_C733del | In Frame Del (DEL) | VAF 11/22 reads (50%) | called by mutect2, pindel, varscan2
- TRAV12-3 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZMYM3 | c.2465C>T p.P822L | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- A4GNT | c.699G>A p.R233= | Silent (SNP) | VAF 226/652 reads (35%) | catalogued as COSV52628469; called by muse, mutect2, varscan2
- AC008397.2 | c.1539C>T p.T513= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV53205048; called by muse, mutect2, varscan2
- ACTL6A | c.450C>T p.F150= | Silent (SNP) | VAF 105/193 reads (54%) | catalogued as COSV66998659; called by muse, mutect2, varscan2
- ADAM22 | c.1962G>A p.G654= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs766868214, COSV55970603; called by muse, mutect2, varscan2
- ADGRG3 | c.183C>T p.S61= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as COSV100341923, COSV59650290; called by muse, mutect2, varscan2
- ADGRG4 | c.4452G>A p.R1484= | Silent (SNP) | VAF 66/83 reads (80%) | catalogued as rs1216761001, COSV54950406; called by muse, mutect2, varscan2
- AKAP8 | c.1599G>A p.V533= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as COSV54101185; called by muse, mutect2
- ALOX15B | c.927C>T p.F309= | Silent (SNP) | VAF 35/68 reads (51%) | catalogued as COSV66479031, COSV66479840; called by muse, mutect2, varscan2
- AMDHD2 | c.741C>T p.I247= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as rs373305868; called by muse, mutect2, varscan2
- ANK2 | c.11709C>T p.I3903= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV52147931; called by muse, mutect2, varscan2
- APOB | c.11062C>T p.L3688= | Silent (SNP) | VAF 228/674 reads (34%) | catalogued as COSV51924752, COSV51938093; called by muse, mutect2, varscan2
- APOL4 | c.696T>C p.F232= (on ENST00000352371 / NM_145660.2; = p.F229= on NM_030643.4) | Silent (SNP) | VAF 55/60 reads (92%) | catalogued as COSV60654039; called by muse, mutect2, varscan2
- ASPHD2 | c.540C>T p.S180= | Silent (SNP) | VAF 35/38 reads (92%) | catalogued as COSV53218163; called by muse, mutect2, varscan2
- ATF4 | c.150C>T p.S50= | Silent (SNP) | VAF 68/74 reads (92%) | catalogued as rs1223875615, COSV57477676; called by muse, mutect2, varscan2
- ATF6B | c.1209C>T p.F403= | Silent (SNP) | VAF 73/553 reads (13%) | catalogued as COSV64351336; called by muse, mutect2, varscan2
- ATP13A4 | c.3429C>T p.F1143= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs117452828; called by muse, mutect2, varscan2
- ATP13A4 | c.1488G>A p.L496= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as rs369206909; called by muse, mutect2, varscan2
- ATP2B1 | c.291C>T p.T97= | Silent (SNP) | VAF 96/240 reads (40%) | catalogued as COSV53804253; called by muse, mutect2, varscan2
- ATP7B | c.945C>T p.I315= | Silent (SNP) | VAF 68/269 reads (25%) | catalogued as rs776855440, COSV54435505; called by muse, mutect2, varscan2
- BBOX1 | c.258C>T p.F86= | Silent (SNP) | VAF 83/94 reads (88%) | catalogued as COSV54189438, COSV54191456; called by muse, mutect2, varscan2
- BBX | c.2811C>T p.S937= (on ENST00000325805 / NM_001142568.3; = p.S907= on NM_020235.7) | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as rs1002178285, COSV57879627; called by muse, mutect2, varscan2
- BDKRB1 | c.327C>T p.L109= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as COSV53705367; called by muse, mutect2, varscan2
- BRSK1 | c.537C>T p.S179= | Silent (SNP) | VAF 94/297 reads (32%) | catalogued as COSV58664873; called by muse, mutect2, varscan2
- C1QTNF1 | c.366G>A p.R122= | Silent (SNP) | VAF 47/122 reads (39%) | catalogued as COSV59260716; called by muse, mutect2, varscan2
- C5AR1 | c.630C>T p.G210= | Silent (SNP) | VAF 56/184 reads (30%) | catalogued as COSV61892170; called by muse, mutect2, varscan2
- CACNA1A | c.1389G>A p.L463= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV64190715; called by muse, mutect2, varscan2
- CACNA1F | c.5751C>T p.F1917= | Silent (SNP) | VAF 11/13 reads (85%) | catalogued as rs1352913123, COSV59903205; called by muse, mutect2, varscan2
- CACNA1S | c.4680G>A p.R1560= | Silent (SNP) | VAF 39/118 reads (33%) | catalogued as COSV62936528; called by muse, mutect2, varscan2
- CAPN12 | c.120G>A p.L40= | Silent (SNP) | VAF 39/77 reads (51%) | catalogued as COSV61014854; called by muse, mutect2, varscan2
- CAPN13 | c.1812G>A p.G604= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs1286530880, COSV54428636; called by muse, mutect2, varscan2
- CBFA2T3 | c.618G>A p.L206= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as COSV51923656; called by muse, mutect2, varscan2
- CCR3 | c.747C>T p.F249= | Silent (SNP) | VAF 51/83 reads (61%) | catalogued as rs76939117, COSV62461759; called by muse, mutect2, varscan2
- CCR9 | c.978G>A p.R326= (on ENST00000357632 / NM_031200.3; = p.R314= on NM_006641.4) | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV62939876; called by muse, mutect2, varscan2
- CDC37L1 | c.753G>A p.E251= | Silent (SNP) | VAF 24/31 reads (77%) | catalogued as COSV67865739; called by muse, mutect2, varscan2
- CDH13 | c.2010G>A p.T670= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as rs369416157; called by muse, mutect2, varscan2
- CDH23 | c.2031C>T p.F677= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs759239589, COSV54925526; called by muse, mutect2, varscan2
- CEACAM5 | c.1348C>T p.L450= | Silent (SNP) | VAF 48/85 reads (56%) | catalogued as COSV55750882; called by muse, mutect2, varscan2
- CERKL | c.303G>A p.V101= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV59203881; called by muse, mutect2, varscan2
- CLEC3A | c.330C>T p.I110= (on ENST00000651443; = p.I101= on NM_005752.6) | Silent (SNP) | VAF 47/79 reads (59%) | catalogued as COSV55219839; called by muse, mutect2, varscan2
- CNNM4 | c.1458C>T p.P486= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as COSV65660276; called by muse, mutect2
- COL10A1 | c.657G>A p.V219= | Silent (SNP) | VAF 30/33 reads (91%) | catalogued as COSV54572265, COSV99684451; called by muse, mutect2, varscan2
- COL19A1 | c.1176C>T p.S392= | Silent (SNP) | VAF 34/37 reads (92%) | catalogued as rs755499242, COSV59566188; called by muse, mutect2, varscan2
- COL3A1 | c.3270A>C p.P1090= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV58582570; called by muse, mutect2
- CPS1 | c.1215C>T p.T405= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs868753057, COSV51803077; called by muse, mutect2, varscan2
- CRACDL | c.486G>A p.R162= | Silent (SNP) | VAF 62/103 reads (60%) | catalogued as COSV67406697; called by muse, mutect2, varscan2
- CSMD2 | c.4854C>T p.P1618= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as COSV53883753; called by muse, mutect2, varscan2
- CUX1 | c.4380C>T p.F1460= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs1226555885, COSV52892022; called by muse, mutect2, varscan2
- CYFIP2 | c.3531C>T p.F1177= (on ENST00000616178 / NM_001291722.2; = p.F1152= on NM_014376.4) | Silent (SNP) | VAF 112/269 reads (42%) | catalogued as rs1207573885, COSV59029292; called by muse, mutect2, varscan2
- CYP4F11 | c.1563G>A p.A521= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs1296561213, COSV56125770; called by muse, mutect2, varscan2
- CYP4X1 | c.786C>T p.I262= | Silent (SNP) | VAF 16/20 reads (80%) | catalogued as COSV64149744; called by muse, mutect2, varscan2
- CYTIP | c.1029A>G p.K343= | Silent (SNP) | VAF 41/70 reads (59%) | catalogued as COSV51632114; called by muse, mutect2, varscan2
- DBF4B | c.729C>T p.F243= | Silent (SNP) | VAF 55/107 reads (51%) | catalogued as COSV59259162; called by muse, mutect2, varscan2
- DCAF1 | c.3258C>T p.F1086= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs782069585, COSV60040871; called by muse, varscan2
- DCAF11 | c.1164C>T p.S388= | Silent (SNP) | VAF 59/123 reads (48%) | catalogued as COSV58108344; called by muse, mutect2, varscan2
- DCSTAMP | c.906C>T p.I302= | Silent (SNP) | VAF 101/303 reads (33%) | catalogued as COSV52576299; called by muse, mutect2, varscan2
- DLEU7 | c.381G>A p.S127= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV68546590; called by muse, mutect2, varscan2
- DNA2 | c.2847C>T p.I949= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV64427538; called by muse, mutect2, varscan2
- DNAH7 | c.11982G>A p.T3994= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs781492764, COSV56753497; called by muse, mutect2, varscan2
- DNAH8 | c.9258G>A p.Q3086= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV59427898; called by muse, mutect2, varscan2
- DNAH8 | c.10653C>T p.I3551= | Silent (SNP) | VAF 65/387 reads (17%) | catalogued as COSV59427927, COSV59461879, COSV59468585; called by muse, mutect2, varscan2
- DNAH9 | c.8013C>T p.I2671= | Silent (SNP) | VAF 83/167 reads (50%) | catalogued as COSV52335995; called by muse, mutect2, varscan2
- DNAJA2 | c.507C>T p.I169= | Silent (SNP) | VAF 65/114 reads (57%) | catalogued as COSV57694403; called by muse, mutect2, varscan2
- DOK7 | c.210C>T p.P70= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100403583; called by muse, mutect2, varscan2
- DYTN | c.1692C>T p.A564= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV101484375; called by muse, mutect2, varscan2
- ENPP1 | c.2460C>T p.I820= | Silent (SNP) | VAF 22/24 reads (92%) | catalogued as COSV62930378; called by muse, mutect2, varscan2
- EXTL3 | c.244C>T p.L82= | Silent (SNP) | VAF 43/65 reads (66%) | catalogued as COSV55036876; called by muse, mutect2, varscan2
- F10 | c.519G>A p.G173= | Silent (SNP) | VAF 26/163 reads (16%) | catalogued as rs1219278109, COSV65020842; called by muse, mutect2, varscan2
- F11R | c.267C>T p.F89= | Silent (SNP) | VAF 59/104 reads (57%) | catalogued as COSV57036167; called by muse, mutect2, varscan2
- F13B | c.1488C>T p.T496= | Silent (SNP) | VAF 43/98 reads (44%) | catalogued as rs780141949, COSV66372435; called by muse, mutect2, varscan2
- F2 | c.582G>A p.A194= | Silent (SNP) | VAF 68/78 reads (87%) | catalogued as rs376545041, COSV100319462; called by muse, mutect2, varscan2
- FAM160B2 | c.1809C>T p.F603= | Silent (SNP) | VAF 23/33 reads (70%) | catalogued as COSV57157132; called by muse, mutect2, varscan2
- FAM189B | c.1914C>T p.S638= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs1223372759, COSV59169024; called by muse, mutect2, varscan2
- FBLN2 | c.2607C>T p.C869= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs370478394; called by muse, mutect2, varscan2
- FBN1 | c.4989T>C p.C1663= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV57310239, COSV57334345; called by muse, mutect2, varscan2
- FBXW4 | c.897C>T p.F299= | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as rs868275299, COSV58706853; called by muse, mutect2, varscan2
- FCF1 | c.465C>T p.Y155= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs1243134667, COSV62043867; called by muse, mutect2, varscan2
- FGF10 | c.561G>A p.R187= | Silent (SNP) | VAF 51/123 reads (41%) | catalogued as COSV52932273; called by muse, mutect2, varscan2
- FGF12 | c.558G>A p.G186= (on ENST00000454309 / NM_021032.5; = p.G124= on NM_004113.6) | Silent (SNP) | VAF 115/192 reads (60%) | catalogued as COSV53154141; called by muse, mutect2, varscan2
- FHOD3 | c.3441C>T p.I1147= (on ENST00000359247 / NM_001281739.3; = p.I1164= on NM_025135.5) | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as rs754477560, COSV57165551; called by muse, mutect2, varscan2
- FIBIN | c.537C>T p.I179= | Silent (SNP) | VAF 36/44 reads (82%) | catalogued as rs1351860248, COSV59412484; called by muse, mutect2, varscan2
- FN1 | c.2847G>A p.E949= | Silent (SNP) | VAF 30/53 reads (57%) | catalogued as COSV60547414; called by muse, mutect2, varscan2
- FPR2 | c.438C>T p.I146= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as rs200320548, COSV100389426, COSV60672026; called by muse, mutect2, varscan2
- FRY | c.3960C>T p.A1320= | Silent (SNP) | VAF 21/159 reads (13%) | catalogued as COSV66565765; called by muse, mutect2, varscan2
- GABRA3 | c.1194C>T p.I398= | Silent (SNP) | VAF 89/108 reads (82%) | catalogued as rs756972982, COSV64795660; called by muse, mutect2, varscan2
- GABRB3 | c.615G>A p.R205= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as COSV54651806; called by muse, mutect2, varscan2
- GABRE | c.1089C>T p.F363= | Silent (SNP) | VAF 29/33 reads (88%) | catalogued as COSV64818969; called by muse, mutect2, varscan2
- GCSAML | c.240C>T p.S80= | Silent (SNP) | VAF 48/91 reads (53%) | catalogued as COSV63577163; called by muse, mutect2, varscan2
- GDF10 | c.1380G>A p.R460= | Silent (SNP) | VAF 70/151 reads (46%) | called by muse, mutect2, varscan2
- GIMAP1 | c.651C>T p.G217= | Silent (SNP) | VAF 11/14 reads (79%) | catalogued as rs777018083, COSV56187217; called by muse, mutect2
- GLDC | c.648G>A p.R216= | Silent (SNP) | VAF 46/56 reads (82%) | catalogued as COSV58676771; called by muse, mutect2, varscan2
- GLYR1 | c.846C>T p.I282= | Silent (SNP) | VAF 65/134 reads (49%) | catalogued as rs1567691599, COSV58925760; called by muse, mutect2, varscan2
- GOLGA3 | c.231C>T p.D77= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as rs747740074, COSV52626090; called by muse, mutect2, varscan2
- GPAM | c.939C>T p.F313= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV62080360; called by muse, mutect2, varscan2
- GPR68 | c.570C>T p.F190= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV53175557; called by muse, mutect2, varscan2
- GPR78 | c.687C>T p.L229= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as rs200777923, COSV66762556; called by muse, mutect2
- GUSB | c.640C>T p.L214= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV59220993; called by muse, mutect2, varscan2
- H2BC9 | c.261T>C p.R87= | Silent (SNP) | VAF 73/238 reads (31%) | catalogued as COSV55099431; called by muse, mutect2, varscan2
- H3C3 | c.366C>T p.P122= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as rs1343842016, COSV63550694; called by muse, mutect2, varscan2
- HADHB | c.675C>T p.H225= | Silent (SNP) | VAF 42/145 reads (29%) | catalogued as COSV58544908; called by muse, mutect2, varscan2
- HELZ | c.4435C>T p.L1479= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV62376524; called by muse, mutect2, varscan2
- HINT3 | c.510T>C p.F170= | Silent (SNP) | VAF 42/51 reads (82%) | catalogued as rs1425525208, COSV57649368; called by muse, mutect2, varscan2
- HK1 | c.861C>T p.N287= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1328964288, COSV53853821; called by muse, mutect2, varscan2
- HOGA1 | c.636C>T p.T212= | Silent (SNP) | VAF 62/164 reads (38%) | catalogued as COSV65706276; called by muse, varscan2
- HS3ST4 | c.912G>A p.K304= | Silent (SNP) | VAF 50/170 reads (29%) | catalogued as COSV58803239, COSV58814154; called by muse, mutect2, varscan2
- HSD3B1 | c.616C>T p.L206= | Silent (SNP) | VAF 53/61 reads (87%) | catalogued as COSV52489657; called by muse, mutect2, varscan2
- HTR3C | c.1074G>T p.G358= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV59174404; called by muse, mutect2, varscan2
- IGFBPL1 | c.696C>T p.P232= | Silent (SNP) | VAF 35/36 reads (97%) | catalogued as rs755719618, COSV66617796; called by muse, mutect2, varscan2
- IPO4 | c.888C>T p.F296= | Silent (SNP) | VAF 71/155 reads (46%) | catalogued as rs1210051189, COSV55778346; called by muse, mutect2, varscan2
- ITGA8 | c.3156G>A p.R1052= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as rs756960220, COSV65225188; called by muse, mutect2, varscan2
- KANSL3 | c.1947C>T p.S649= (on ENST00000666923 / NM_001349262.2; = p.S623= on NM_001115016.3) | Silent (SNP) | VAF 53/90 reads (59%) | catalogued as rs1278098703, COSV62615828; called by muse, mutect2, varscan2
- KAT2A | c.1083C>T p.S361= | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as COSV56789429; called by muse, mutect2, varscan2
- KCNH1 | c.2574G>A p.S858= (on ENST00000271751 / NM_172362.3; = p.S831= on NM_002238.4) | Silent (SNP) | VAF 90/181 reads (50%) | catalogued as rs753475175, COSV55070891, COSV55105645; called by muse, mutect2, varscan2
- KDM5B | c.2100C>T p.F700= | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as rs1275226706, COSV52504694; called by muse, mutect2, varscan2
- KIAA1549 | c.5376C>T p.A1792= | Silent (SNP) | VAF 23/35 reads (66%) | catalogued as COSV54306690; called by muse, mutect2, varscan2
- KIFC1 | c.1722C>T p.P574= | Silent (SNP) | VAF 235/345 reads (68%) | catalogued as rs769160369, COSV65728612; called by muse, mutect2, varscan2
- KLHL13 | c.519C>T p.F173= | Silent (SNP) | VAF 41/48 reads (85%) | catalogued as COSV53245064; called by muse, mutect2, varscan2
- KLK5 | c.264C>T p.P88= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV60449595; called by muse, mutect2, varscan2
- KRT20 | c.141C>T p.S47= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as rs1359699404, COSV51424041; called by muse, mutect2, varscan2
- KRT74 | c.1005C>T p.T335= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV59770630; called by muse, mutect2, varscan2
- KRT76 | c.1878C>T p.S626= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as rs376438589; called by muse, mutect2, varscan2
- KRTAP13-4 | c.42C>T p.S14= | Silent (SNP) | VAF 52/142 reads (37%) | catalogued as COSV61878631; called by muse, mutect2, varscan2
- KSR2 | c.1809A>G p.E603= | Silent (SNP) | VAF 64/147 reads (44%) | catalogued as COSV56666579; called by muse, mutect2, varscan2
- LCE1A | c.183C>T p.S61= | Silent (SNP) | VAF 52/114 reads (46%) | catalogued as rs753167540, COSV58726539; called by muse, mutect2, varscan2
- LHFPL5 | c.264C>T p.S88= | Silent (SNP) | VAF 94/416 reads (23%) | catalogued as rs1561950842, COSV64177204, COSV64178439; called by muse, mutect2, varscan2
- LILRA2 | c.840C>T p.F280= | Silent (SNP) | VAF 60/99 reads (61%) | catalogued as rs1568508330, COSV52188416; called by muse, mutect2, varscan2
- LNP1 | c.141C>T p.T47= | Silent (SNP) | VAF 41/142 reads (29%) | catalogued as COSV67346204; called by muse, mutect2, varscan2
- LPA | c.4294C>T p.L1432= | Silent (SNP) | VAF 36/43 reads (84%) | catalogued as rs761418281, COSV60297621; called by muse, mutect2, varscan2
- LRP2 | c.8220C>T p.T2740= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV55542361, COSV99790786; called by muse, mutect2, varscan2
- LRRC25 | c.48G>A p.R16= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as COSV59114705; called by muse, mutect2, varscan2
- LRRC66 | c.1887C>T p.S629= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs770933207, COSV58632215; called by muse, mutect2, varscan2
- LRRIQ3 | c.1641G>A p.E547= | Silent (SNP) | VAF 43/51 reads (84%) | catalogued as COSV63041478, COSV63045443; called by muse, mutect2, varscan2
- LRRN1 | c.381G>A p.E127= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV60012531; called by muse, mutect2
- LRTM1 | c.921C>T p.A307= | Silent (SNP) | VAF 81/129 reads (63%) | catalogued as COSV55517409, COSV55586722; called by muse, mutect2, varscan2
- LSMEM1 | c.348C>T p.I116= | Silent (SNP) | VAF 49/76 reads (64%) | catalogued as rs760065924, COSV57196070; called by muse, mutect2, varscan2
- MAGEB6B | c.39G>A p.G13= | Silent (SNP) | VAF 47/62 reads (76%) | called by muse, mutect2, varscan2
- MBD5 | c.1221C>T p.L407= | Silent (SNP) | VAF 52/140 reads (37%) | catalogued as rs950136624, COSV68695857, COSV68698950; called by muse, mutect2, varscan2
- MCF2L | c.1491G>A p.Q497= (on ENST00000375608; = p.Q465= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as rs748835491, COSV65048634; called by muse, mutect2, varscan2
- MCMBP | c.534C>T p.P178= | Silent (SNP) | VAF 80/204 reads (39%) | catalogued as rs754467107, COSV63508560; called by muse, varscan2
- MCMDC2 | c.702C>T p.F234= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV58034065; called by muse, mutect2, varscan2
- MEPCE | c.1006C>T p.L336= | Silent (SNP) | VAF 140/184 reads (76%) | catalogued as rs748007496, COSV52768761; called by muse, mutect2, varscan2
- MGAT4A | c.348G>A p.L116= | Silent (SNP) | VAF 41/83 reads (49%) | catalogued as COSV53845499; called by muse, mutect2, varscan2
- MGAT5B | c.1452C>T p.I484= (on ENST00000569840 / NM_001199172.2; = p.I482= on NM_144677.3) | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs1215251072, COSV56925863; called by muse, mutect2, varscan2
- MLXIP | c.1888C>T p.L630= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV59834133; called by muse, mutect2, varscan2
- MSS51 | c.97C>T p.L33= | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as rs776559249, COSV55018646; called by muse, mutect2, varscan2
- MTSS1 | c.99C>T p.F33= | Silent (SNP) | VAF 35/111 reads (32%) | catalogued as COSV61495132; called by muse, mutect2, varscan2
- MUC16 | c.29293C>T p.L9765= | Silent (SNP) | VAF 29/53 reads (55%) | catalogued as rs780784361, COSV67447624; called by muse, mutect2, varscan2
- MUC16 | c.11646C>T p.I3882= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as rs569691840, COSV67447642; called by muse, mutect2, varscan2
- MYCBPAP | c.2787C>T p.P929= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV52137829; called by muse, mutect2, varscan2
- MYH2 | c.915G>A p.L305= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV55432343; called by muse, mutect2, varscan2
- MYL3 | c.399C>T p.F133= | Silent (SNP) | VAF 58/153 reads (38%) | catalogued as rs112992334, COSV52767346; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO15A | c.282G>A p.K94= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV52752449; called by muse, mutect2, varscan2
- MYO5B | c.1857C>T p.P619= | Silent (SNP) | VAF 39/121 reads (32%) | catalogued as COSV53212124; called by muse, mutect2, varscan2
- MYT1L | c.1272C>T p.F424= | Silent (SNP) | VAF 63/100 reads (63%) | catalogued as rs553083381, COSV67708347, COSV67709367; called by muse, mutect2, varscan2
- N4BP1 | c.927T>A p.I309= | Silent (SNP) | VAF 45/126 reads (36%) | catalogued as COSV52209611; called by muse, mutect2, varscan2
- NCKIPSD | c.588C>T p.A196= | Silent (SNP) | VAF 40/64 reads (63%) | catalogued as COSV53659844; called by muse, mutect2, varscan2
- NDE1 | c.108C>T p.L36= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV61270464; called by muse, mutect2, varscan2
- NLRP13 | c.919C>T p.L307= | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as COSV61620176; called by muse, mutect2, varscan2
- NLRP4 | c.699C>T p.F233= | Silent (SNP) | VAF 56/99 reads (57%) | catalogued as rs577037043, COSV56708587; called by muse, mutect2, varscan2
- NOL6 | c.1248C>T p.F416= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV53039489; called by muse, mutect2, varscan2
- NPAP1 | c.399G>A p.P133= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs750902724, COSV61504850; called by muse, mutect2, varscan2
- NPC1 | c.2427C>T p.S809= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as rs745542071, COSV52576635; called by muse, mutect2, varscan2
- NPTX2 | c.1053C>T p.I351= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV55716246, COSV99674957; called by muse, mutect2
- NSMAF | c.327C>T p.F109= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV50684198; called by muse, mutect2, varscan2
- NT5DC3 | c.1440C>T p.F480= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV67321172, COSV67321557; called by muse, mutect2, varscan2
- NUAK1 | c.1080C>T p.V360= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV54600751; called by muse, mutect2, varscan2
- OBSCN | c.19332G>T p.L6444= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as COSV62172677, COSV63449201; called by muse, mutect2, varscan2
- OR10G2 | c.93C>T p.L31= | Silent (SNP) | VAF 53/105 reads (50%) | catalogued as COSV73390313; called by muse, mutect2, varscan2
- OR10J1 | c.93C>T p.F31= | Silent (SNP) | VAF 98/214 reads (46%) | catalogued as rs867477313, COSV71128238; called by muse, mutect2, varscan2
- OR10K2 | c.639G>A p.L213= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV59220500, COSV59221753; called by muse, mutect2, varscan2
- OR11L1 | c.468C>T p.G156= | Silent (SNP) | VAF 71/153 reads (46%) | catalogued as COSV63313763; called by muse, mutect2, varscan2
- OR1A2 | c.87G>A p.V29= | Silent (SNP) | VAF 54/149 reads (36%) | catalogued as COSV67936120; called by muse, mutect2, varscan2
- OR2A2 | c.120G>A p.G40= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as COSV68871128; called by muse, mutect2, varscan2
- OR2D3 | c.36G>A p.Q12= | Silent (SNP) | VAF 26/26 reads (100%) | catalogued as COSV58572538; called by muse, mutect2, varscan2
- OR2J2 | c.342C>T p.V114= | Silent (SNP) | VAF 355/513 reads (69%) | catalogued as COSV65847753; called by muse, mutect2, varscan2
- OR2J3 | c.828C>T p.F276= | Silent (SNP) | VAF 54/165 reads (33%) | catalogued as COSV65848685; called by muse, mutect2, varscan2
- OR5T1 | c.291C>T p.F97= | Silent (SNP) | VAF 40/46 reads (87%) | catalogued as COSV57301770; called by muse, mutect2, varscan2
- OTOF | c.4287C>T p.F1429= (on ENST00000272371 / NM_194248.3; = p.F662= on NM_004802.4) | Silent (SNP) | VAF 51/92 reads (55%) | catalogued as COSV55496761; called by muse, mutect2, varscan2
- OXR1 | c.279G>A p.Q93= (on ENST00000442977 / NM_001198532.1; = p.Q92= on NM_018002.3) | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV56324765; called by muse, mutect2, varscan2
- PACS1 | c.688C>T p.L230= | Silent (SNP) | VAF 34/40 reads (85%) | catalogued as COSV57696380; called by muse, mutect2, varscan2
- PAGE1 | c.174G>A p.E58= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as COSV65997689; called by muse, mutect2, varscan2
- PARP14 | c.171C>T p.F57= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV72111685, COSV72111778; called by muse, mutect2, varscan2
- PCDH15 | c.4095G>A p.K1365= | Silent (SNP) | VAF 30/50 reads (60%) | catalogued as COSV57267577, COSV57339717; called by muse, mutect2, varscan2
- PCDH15 | c.2811G>A p.P937= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs1449039709, COSV57267597; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDH18 | c.690C>T p.S230= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV61266622; called by muse, mutect2, varscan2
- PCDHA13 | c.1872G>A p.V624= | Silent (SNP) | VAF 43/107 reads (40%) | catalogued as COSV56480372; called by muse, mutect2, varscan2
- PCDHGA4 | c.1632C>T p.I544= | Silent (SNP) | VAF 63/157 reads (40%) | catalogued as rs947858485, COSV53905255; called by muse, mutect2, varscan2
- PCK1 | c.1656C>T p.L552= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV60126344, COSV60127053; called by muse, mutect2, varscan2
- PDILT | c.810C>T p.S270= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs369987602; called by muse, mutect2, varscan2
- PDZD2 | c.2166G>A p.K722= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV56851754; called by muse, mutect2, varscan2
- PHLPP2 | c.2343A>G p.S781= | Silent (SNP) | VAF 91/149 reads (61%) | catalogued as COSV62422777; called by muse, mutect2, varscan2
- PITPNM2 | c.1218C>T p.I406= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs537451071, COSV54896486; called by muse, mutect2, varscan2
- PKD1L1 | c.5640G>A p.V1880= | Silent (SNP) | VAF 12/17 reads (71%) | catalogued as COSV56958734; called by muse, mutect2, varscan2
- PLCH1 | c.174G>A p.K58= (on ENST00000340059 / NM_001130960.2; = p.K70= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 130/234 reads (56%) | catalogued as COSV58188332; called by muse, mutect2, varscan2
- PLEK | c.723C>T p.F241= | Silent (SNP) | VAF 40/143 reads (28%) | catalogued as COSV52250725; called by muse, mutect2, varscan2
- PLXNA1 | c.4245C>T p.L1415= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV52522676; called by muse, mutect2, varscan2
- POM121L12 | c.525G>A p.R175= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs1395465893, COSV68692316; called by muse, mutect2
- PPP2R2B | c.849G>A p.S283= (on ENST00000394409; = p.S349= on NM_181674.2) | Silent (SNP) | VAF 33/66 reads (50%) | catalogued as rs748939898, COSV100355257, COSV60755031; called by muse, mutect2, varscan2
- PRAMEF12 | c.597G>A p.T199= | Silent (SNP) | VAF 82/102 reads (80%) | catalogued as rs1211981422, COSV63214785; called by muse, mutect2, varscan2
- PREX2 | c.2799C>T p.F933= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as COSV55753083; called by muse, mutect2, varscan2
- PRUNE1 | c.615C>T p.F205= | Silent (SNP) | VAF 40/153 reads (26%) | catalogued as rs1193850042, COSV54956943; called by muse, mutect2, varscan2
- PSG4 | c.495G>A p.V165= | Silent (SNP) | VAF 82/256 reads (32%) | catalogued as COSV54933224; called by muse, mutect2, varscan2
- PSKH2 | c.489C>T p.I163= | Silent (SNP) | VAF 52/86 reads (60%) | catalogued as COSV52609343; called by muse, mutect2, varscan2
- PSMD3 | c.1083C>T p.F361= | Silent (SNP) | VAF 63/148 reads (43%) | catalogued as COSV52856564; called by muse, mutect2, varscan2
- PTK7 | c.1902C>T p.P634= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as COSV100030222, COSV57846608; called by muse, mutect2, varscan2
- PTPA | c.339C>T p.V113= (on ENST00000337738 / NM_178001.2; = p.V78= on NM_021131.5) | Silent (SNP) | VAF 38/48 reads (79%) | catalogued as rs748371662, COSV61233997; called by muse, mutect2, varscan2
- QSOX1 | c.702C>T p.F234= | Silent (SNP) | VAF 70/214 reads (33%) | catalogued as COSV62579694; called by muse, varscan2
- RASGRF1 | c.162C>T p.F54= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV69176849; called by muse, mutect2, varscan2
- RECQL5 | c.1959G>A p.K653= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV58637817; called by muse, mutect2, varscan2
- RIPOR2 | c.198C>T p.P66= | Silent (SNP) | VAF 56/169 reads (33%) | catalogued as COSV52417890; called by muse, mutect2, varscan2
- RNF10 | c.696T>C p.P232= | Silent (SNP) | VAF 71/152 reads (47%) | catalogued as COSV58043723; called by muse, mutect2, varscan2
- SALL3 | c.2595G>A p.V865= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as COSV73305798; called by muse, mutect2, varscan2
- SAMD4B | c.1728C>T p.F576= | Silent (SNP) | VAF 30/51 reads (59%) | catalogued as COSV58750280; called by muse, mutect2, varscan2
- SCN11A | c.2301G>A p.G767= | Silent (SNP) | VAF 35/57 reads (61%) | catalogued as COSV56566344; called by muse, mutect2, varscan2
- SDK1 | c.3288G>A p.G1096= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as COSV67357891; called by muse, mutect2, varscan2
- SEC16B | c.2892C>T p.S964= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs551572241, COSV57623639; called by muse, mutect2, varscan2
- SERPINB12 | c.192C>T p.S64= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as COSV54032197; called by muse, mutect2, varscan2
- SETD3 | c.840C>T p.T280= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs767086863, COSV59282856; called by muse, mutect2, varscan2
- SIM2 | c.549C>T p.I183= | Silent (SNP) | VAF 54/129 reads (42%) | catalogued as COSV51766302; called by muse, mutect2, varscan2
- SIPA1L2 | c.2592C>T p.F864= | Silent (SNP) | VAF 52/165 reads (32%) | catalogued as rs376260317, COSV53391942; called by muse, mutect2, varscan2
- SIT1 | c.111C>T p.S37= | Silent (SNP) | VAF 57/61 reads (93%) | catalogued as COSV52399619; called by muse, mutect2, varscan2
- SLC10A4 | c.517C>T p.L173= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV56718122, COSV99906739; called by muse, mutect2, varscan2
- SLC16A5 | c.1131C>T p.F377= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV61675427; called by muse, mutect2, varscan2
- SLC22A8 | c.1011C>T p.T337= | Silent (SNP) | VAF 20/24 reads (83%) | catalogued as rs762674610, COSV100267832, COSV60323881; called by muse, mutect2
- SLC24A3 | c.1461C>T p.I487= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as rs774544292, COSV60112932; called by muse, mutect2, varscan2
- SLC4A3 | c.2754C>T p.F918= | Silent (SNP) | VAF 30/52 reads (58%) | catalogued as rs776093889, COSV99813213; called by muse, mutect2, varscan2
- SLC4A3 | c.2755C>T p.L919= | Silent (SNP) | VAF 30/52 reads (58%) | catalogued as COSV99813214; called by muse, mutect2, varscan2
- SLC4A5 | c.1563C>T p.S521= | Silent (SNP) | VAF 122/212 reads (58%) | catalogued as COSV61024933; called by muse, mutect2, varscan2
- SPON2 | c.339G>A p.A113= | Silent (SNP) | VAF 32/51 reads (63%) | catalogued as COSV52054337; called by muse, mutect2, varscan2
- ST13 | c.90C>T p.F30= | Silent (SNP) | VAF 55/105 reads (52%) | catalogued as rs1262711290, COSV53420918; called by muse, mutect2, varscan2
- STON1 | c.1777C>T p.L593= | Silent (SNP) | VAF 34/102 reads (33%) | catalogued as COSV59126724; called by muse, mutect2, varscan2
- SUSD1 | c.1833G>A p.E611= | Silent (SNP) | VAF 55/130 reads (42%) | catalogued as COSV62582367; called by muse, mutect2, varscan2
- SYNM | c.1575C>T p.F525= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs569566682, COSV60368014; called by muse, mutect2
- SYNPR | c.504C>T p.I168= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV55722881; called by muse, mutect2, varscan2
- TAF5L | c.537C>T p.L179= | Silent (SNP) | VAF 113/212 reads (53%) | catalogued as COSV51077457; called by muse, mutect2, varscan2
- TBC1D14 | c.1719G>A p.K573= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV68984661; called by muse, mutect2, varscan2
- TEKT5 | c.1455C>T p.T485= | Silent (SNP) | VAF 67/116 reads (58%) | catalogued as rs1264693151, COSV51586826; called by muse, mutect2, varscan2
- TENM2 | c.3792C>T p.P1264= (on ENST00000518659 / NM_001122679.2; = p.P1032= on NM_001080428.3) | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs1282992375, COSV69123542; called by muse, mutect2, varscan2
- TG | c.1503C>T p.F501= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV55066336; called by muse, mutect2, varscan2
60 further variants in this file (0 protein-altering or splice-affecting, 37 silent, 23 other) are not listed here.
